Somatic mutation profile of tumor specimen 0DE7FU from CCDI case PBBPPS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Peritoneum, NOS; Age at diagnosis: 7.1 years (2,590 days).
Specimen 0DE7FU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38eab9d3-18a5-4d71-a3ee-d1f2478fa3f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DE7E7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5f5a5f5-e970-44f3-8813-f5b154639d4b

The open-access MAF lists 51 somatic variants for this specimen: 33 protein-altering or splice-affecting, 9 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 9, Intron 4, 3'UTR 3, Nonsense Mutation 1, 3'Flank 1, Frame Shift Del 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1393C>A p.R465S (on ENST00000281708 / NM_001349798.2; = p.R385S on NM_018315.5) | Missense Mutation (SNP) | VAF 92/244 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55891008, COSV55897912, COSV99654845; called by mutect2, varscan2
- RYR1 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 71/543 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs111888148, CM064221; ClinVar: drug response / pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2
- AKAP3 | c.323G>T p.C108F | Missense Mutation (SNP) | VAF 50/402 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV57414735; called by muse, mutect2, varscan2
- BOC | c.2080G>A p.A694T | Missense Mutation (SNP) | VAF 87/220 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs759707512; called by muse, mutect2, varscan2
- CABLES2 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 213/784 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs747530163, COSV54158410; called by muse, mutect2, varscan2
- CPLX1 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs778302635; called by muse, mutect2, varscan2
- DDX59 | c.790C>G p.R264G | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV58752639; called by muse, mutect2, varscan2
- DYSF | c.1310C>T p.T437M | Missense Mutation (SNP) | VAF 84/596 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs376358025; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELP3 | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 90/384 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs190129217; called by muse, mutect2, varscan2
- GTPBP1 | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 127/631 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as rs1426227409, COSV99323288; called by muse, mutect2, varscan2
- KRBOX1 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 54/297 reads (18%) | catalogued as rs1425569526, COSV67466752; called by muse, mutect2, varscan2
- PGM3 | c.539T>C p.I180T | Missense Mutation (SNP) | VAF 139/504 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs745961996; called by muse, mutect2, varscan2
- PRSS1 | c.152C>A p.S51Y | Missense Mutation (SNP) | VAF 62/470 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs1415566919, COSV61192646, COSV61197642; called by muse, varscan2
- PRSS35 | c.131A>C p.H44P | Missense Mutation (SNP) | VAF 66/347 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1246294380; called by muse, mutect2, varscan2
- RELN | c.7764C>A p.N2588K | Missense Mutation (SNP) | VAF 87/526 reads (17%) | SIFT tolerated (0.9); PolyPhen benign (0.028); catalogued as COSV100632985; called by muse, mutect2, varscan2
- RXYLT1 | c.527A>G p.Y176C | Missense Mutation (SNP) | VAF 58/357 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV99707160; called by muse, mutect2, varscan2
- CLCF1 | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT tolerated (0.91); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- COL4A4 | c.5062A>C p.K1688Q | Missense Mutation (SNP) | VAF 39/288 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); called by muse, varscan2
- FREM2 | c.6321C>G p.N2107K | Missense Mutation (SNP) | VAF 54/371 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GRM1 | c.1442T>C p.I481T | Missense Mutation (SNP) | VAF 230/390 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HTR1F | c.1085T>A p.V362E | Missense Mutation (SNP) | VAF 51/272 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- LILRB5 | c.71-2A>G p.X24_splice | Splice Site (SNP) | VAF 83/341 reads (24%) | called by muse, mutect2, varscan2
- LRRC8E | c.1169A>G p.E390G | Missense Mutation (SNP) | VAF 60/567 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MEGF6 | c.2477G>T p.C826F | Missense Mutation (SNP) | VAF 65/275 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH9 | c.3510C>G p.N1170K | Missense Mutation (SNP) | VAF 98/569 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NUP214 | c.4738del p.E1580Rfs*37 | Frame Shift Del (DEL) | VAF 36/168 reads (21%) | called by mutect2, varscan2
- PPWD1 | c.1547T>G p.V516G | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by mutect2, varscan2
- RNF17 | c.4057T>A p.Y1353N | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SLC26A4 | c.1214C>G p.T405S | Missense Mutation (SNP) | VAF 100/715 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOX2 | c.1316T>C p.I439T (on ENST00000358131 / NM_001098798.2; = p.I415T on NM_032883.3) | Missense Mutation (SNP) | VAF 76/419 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- WASHC2A | c.259C>T p.L87F | Missense Mutation (SNP) | VAF 86/358 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFAND4 | c.1751G>A p.S584N | Missense Mutation (SNP) | VAF 65/215 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZSWIM6 | c.3377A>C p.N1126T | Missense Mutation (SNP) | VAF 61/315 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- ARPP21 | c.579G>A p.S193= | Silent (SNP) | VAF 48/181 reads (27%) | catalogued as rs150267871; called by muse, mutect2, varscan2
- CACNA1B | c.492C>T p.N164= | Silent (SNP) | VAF 141/624 reads (23%) | catalogued as rs756422106, COSV53127102; called by muse, mutect2, varscan2
- EPPK1 | c.6135C>T p.S2045= | Silent (SNP) | VAF 100/561 reads (18%) | catalogued as rs782583923, COSV101599994; called by muse, mutect2, varscan2
- FBXO21 | c.1110C>T p.H370= | Silent (SNP) | VAF 80/536 reads (15%) | catalogued as rs373063082; called by muse, mutect2, varscan2
- FLNC | c.3228G>T p.L1076= | Silent (SNP) | VAF 91/675 reads (13%) | catalogued as COSV57955849; called by muse, mutect2, varscan2
- GPATCH1 | c.939C>T p.D313= | Silent (SNP) | VAF 28/566 reads (5%) | catalogued as rs759547534; called by muse, mutect2
- KEL | c.1083G>T p.L361= | Silent (SNP) | VAF 203/614 reads (33%) | called by muse, mutect2, varscan2
- RRP12 | c.2829G>T p.L943= | Silent (SNP) | VAF 33/210 reads (16%) | called by muse, mutect2, varscan2
- SERGEF | c.852C>T p.G284= | Silent (SNP) | VAF 34/247 reads (14%) | called by muse, mutect2, varscan2
- ERCC6L2 | c.471+29C>G | Intron (SNP) | VAF 6/156 reads (4%) | called by muse, mutect2
- GGTLC1 | c.-23G>T | 5'UTR (SNP) | VAF 22/135 reads (16%) | called by muse, mutect2, varscan2
- H1-8 | chr3:129551391 C>T | 3'Flank (SNP) | VAF 7/60 reads (12%) | catalogued as rs542924424; called by muse, mutect2, varscan2
- HMX3 | c.*986C>T | 3'UTR (SNP) | VAF 26/141 reads (18%) | called by muse, varscan2
- IL20RB | c.*38C>T | 3'UTR (SNP) | VAF 22/111 reads (20%) | called by muse, mutect2, varscan2
- ITSN1 | c.347-16T>C | Intron (SNP) | VAF 35/155 reads (23%) | called by muse, mutect2, varscan2
- MAPK12 | c.*78C>T | 3'UTR (SNP) | VAF 11/53 reads (21%) | catalogued as rs954001100; called by muse, mutect2, varscan2
- TMEM243 | c.129+59A>C | Intron (SNP) | VAF 46/246 reads (19%) | catalogued as rs1238624854; called by muse, mutect2, varscan2
- TPM1 | c.772+69C>A | Intron (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
